Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADL, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADL-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular marrow

Specimen : liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Left lateral sectionectomy

Organs:

Liver (14.0 x 18.0 x 3.5 cm, 555.0 gm)

Gallbladder (10.5 cm in length, 3.0 cm in diameter, 0.2 cm in wall thickness)

Hard tissue (1 piece, 0.7 x 0.6 x 0.5 cm)

Decalcification was done.

Lesion:

A well-defined pale tan round and solid nodule (3.5 x 4.0 x 4.0 cm)
(nodular type)

Resection margin:

Not involved grossly (safety margin: 1.3 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Pre-cirrhotic

Gross photo: Present

Blocks

T1-5, TB, tumor mass x 6

L, NB, liver parenchyma x 2

RM, resection margin x 1

A, hard tissue x 1

GB, gallbladder x 1

MICROSCOPIC:

Tumor type: Hepatocellular carcinoma

Histologic grade (Edmondson-Steiner grade for Hepatocellular carcinoma)

The worst differentiation: IV

The major differentiation: III

Histologic type: Trabecular and pseudoglandular

Cell type: Hepatic and clear

Fatty change: Mild

Fibrous capsule formation: Partial

Capsular infiltration: Yes

Septum formation: Yes

Surgical resection margin invasion: No (safety margin: 1.3 cm)

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: Yes

Intrahepatic metastasis: Unknown

Multicentric occurrence: Unknown

ICD-O-3
Carcinoma, hepatocellular NOS
8170/3

Sitz. Liver
C22.0

Q10 5/20/14

[page 2 of 2]
Fibrosis: Septal (precirrhotic, stage 3)

NOT reported. Gross:

Stomach, antrum, scopic, chronic gastritis, regenerating atypia

Liver, left, segment 3, ectomy, hepatocellular carcinoma

T56000, left, segment 3, P10, M81703

Gallbladder, ectomy, chronic cholecystitis

T57000, P10, M43005

DIAGNOSIS:

Liver, left, segment 3, left lateral sectionectomy:

Hepatocellular carcinoma, poorly differentiated

(Edmondson-Steiner grade 3/4)

Gallbladder, cholecystectomy:

Chronic cholecystitis

Suggestion :

Source: NCI Genomic Data Commons file d44e5040-63b6-45cc-8f69-120d463294e2 (TCGA-DD-AADL.248AF6DC-85A7-4334-B282-B7B0102C4596.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).